MMRF case MMRF_1462 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/07a28bc3-d102-4486-9d26-38ead109d431

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.6 years (21,779 days); ISS stage: I; Days to last known disease status: 1,376 days (3.8 years); Days to last follow up: 1,376 days (3.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 177 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 178 days; Days to treatment end: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 646 days (1.8 years); Days to treatment end: 822 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 890 days (2.4 years); Days to treatment end: 912 days (2.5 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 890 days (2.4 years); Days to treatment end: 910 days (2.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 900 days (2.5 years); Days to treatment end: 912 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 912 days (2.5 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,130 days (3.1 years); Days to treatment end: 1,130 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 6.62 g/L; Immunoglobulin A 37.6 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 10.2 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 10.6 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 0.319 mg/dL.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 3.99 g/L; Immunoglobulin A 12.4 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 9.4 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 8.47 mmol/L.
- Day 178 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 2.87 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 7.43 mmol/L.
- Day 261 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 3.47 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 373 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 4.87 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.23 mmol/L.
- Day 457 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 6.07 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 5.12 mmol/L.
- Day 541 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 6.39 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.72 mmol/L.
- Day 625 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 16.4 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 8.7 g/dL; Glucose 4.79 mmol/L.
- Day 730 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.43 mmol/L.
- Day 822: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 3.98 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 13.9 ×10⁹/L; Absolute Neutrophil 12.2 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 7.65 mmol/L.
- Day 912 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 157 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 17 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 63 ×10⁹/L; Creatinine 238 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 7.59 mmol/L.
- Day 1,003 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 3.99 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 7.65 mmol/L.
- Day 1,094: M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 3.37 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 9.19 mmol/L.
- Day 1,184 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 4.47 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.
- Day 1,271 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 7.32 mmol/L.
- Day 1,376 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 2.89 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day 1: Weight: 118 kg; Height: 176 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (5 samples)
- Sample MMRF_1462_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1462_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1462_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 261 days.
- Sample MMRF_1462_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 625 days (1.7 years).
- Sample MMRF_1462_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 912 days (2.5 years).
